MMRF case MMRF_2363 — Multiple Myeloma CoMMpass Study (MMRF-COMMPASS)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026). Disease type: Plasma Cell Tumors; Primary site: Hematopoietic and reticuloendothelial systems. Index date (day 0 for every day count below): first treatment.
https://portal.gdc.cancer.gov/cases/6ee3a6fb-773e-4678-9cab-28473bb17740

Demographics
Sex at birth: female; Race: white; Ethnicity: not hispanic or latino; Age at index: 52 years; Vital status: Alive.

Diagnoses (1)
1. Multiple myeloma: ICD-O-3 morphology code: 9732/3; Tissue or organ of origin: Bone marrow; Site of resection or biopsy: Bone marrow; Age at diagnosis: 53.0 years (19,353 days); ISS stage: I; Days to last known disease status: 723 days (2.0 years); Days to last follow up: 723 days (2.0 years).
   Treatment given: Therapeutic agents: Carfilzomib; Regimen or line of therapy: First line of therapy; Days to treatment start: 1 day; Days to treatment end: 2 days.
   Treatment given: Therapeutic agents: Dexamethasone; Regimen or line of therapy: First line of therapy; Days to treatment start: 1 day.
   Treatment given: Therapeutic agents: Carfilzomib; Regimen or line of therapy: First line of therapy; Days to treatment start: 3 days.
   Treatment given: Treatment type: Stem Cell Transplantation, Autologous; Regimen or line of therapy: First line of therapy; Days to treatment start: 386 days (1.1 years); Days to treatment end: 386 days (1.1 years).

Molecular and laboratory tests (laboratory values one line per visit day; values rounded to 3 significant figures where GDC's unit conversion carried more)
- Day -13 (ECOG 1): M Protein 2.1 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 19.4 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 0.09 mg/dL; Immunoglobulin G 31.6 g/L; Immunoglobulin A 0.14 g/L; Immunoglobulin M 0.16 g/L; Beta 2 Microglobulin 1.6 µg/mL; Lactate Dehydrogenase 2.25 µkat/L; Hemoglobin 7.13 mmol/L; Leukocytes 3 ×10⁹/L; Absolute Neutrophil 1.5 ×10⁹/L; Platelets 204 ×10⁹/L; Creatinine 64.5 µmol/L; Blood Urea Nitrogen 3.57 mmol/L; Calcium 2.3 mmol/L; Albumin 43 g/L; Total Protein 8.3 g/dL; Glucose 4.79 mmol/L; C-Reactive Protein 0.233 mg/dL.
- Day 91 (ECOG 1): M Protein 0.6 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 7.64 mg/dL; Immunoglobulin G 13.8 g/L; Immunoglobulin A 0.08 g/L; Immunoglobulin M 0.11 g/L; Lactate Dehydrogenase 2.4 µkat/L; Hemoglobin 7.13 mmol/L; Leukocytes 4.2 ×10⁹/L; Absolute Neutrophil 3.1 ×10⁹/L; Platelets 213 ×10⁹/L; Creatinine 61.9 µmol/L; Blood Urea Nitrogen 5.71 mmol/L; Calcium 2.28 mmol/L; Albumin 40 g/L; Total Protein 6.5 g/dL; Glucose 4.68 mmol/L.
- Day 174 (ECOG 1): M Protein 0.8 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 8.45 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 0.05 mg/dL; Immunoglobulin G 14.2 g/L; Immunoglobulin A 0.09 g/L; Immunoglobulin M 0.09 g/L; Lactate Dehydrogenase 2.57 µkat/L; Hemoglobin 7.13 mmol/L; Leukocytes 2.3 ×10⁹/L; Absolute Neutrophil 1.4 ×10⁹/L; Platelets 253 ×10⁹/L; Creatinine 61 µmol/L; Blood Urea Nitrogen 4.64 mmol/L; Calcium 2.25 mmol/L; Albumin 41 g/L; Total Protein 6.7 g/dL; Glucose 5.67 mmol/L.
- Day 273 (ECOG 1): M Protein 0.8 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 7.97 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 0.06 mg/dL; Immunoglobulin G 13.5 g/L; Immunoglobulin A 0.07 g/L; Immunoglobulin M 0.08 g/L; Lactate Dehydrogenase 2.17 µkat/L; Hemoglobin 6.82 mmol/L; Leukocytes 2.9 ×10⁹/L; Absolute Neutrophil 2.1 ×10⁹/L; Platelets 285 ×10⁹/L; Creatinine 61.9 µmol/L; Blood Urea Nitrogen 2.5 mmol/L; Calcium 2.25 mmol/L; Albumin 37 g/L; Total Protein 6.4 g/dL; Glucose 4.95 mmol/L.
- Day 364 (ECOG 1): M Protein 0.6 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 6.41 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 0.23 mg/dL; Immunoglobulin G 13.4 g/L; Immunoglobulin A 0.15 g/L; Immunoglobulin M 0.1 g/L; Lactate Dehydrogenase 2.3 µkat/L; Hemoglobin 7.5 mmol/L; Leukocytes 3.5 ×10⁹/L; Absolute Neutrophil 2.5 ×10⁹/L; Platelets 279 ×10⁹/L; Creatinine 58.3 µmol/L; Blood Urea Nitrogen 2.86 mmol/L; Calcium 2.3 mmol/L; Albumin 42 g/L; Total Protein 6.8 g/dL; Glucose 4.79 mmol/L.
- Day 451 (ECOG 2): M Protein 0.3 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 1.62 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 0.14 mg/dL; Immunoglobulin G 8.22 g/L; Immunoglobulin A 0.3 g/L; Immunoglobulin M 0.17 g/L; Lactate Dehydrogenase 2.7 µkat/L; Hemoglobin 7.56 mmol/L; Leukocytes 4.1 ×10⁹/L; Absolute Neutrophil 2.9 ×10⁹/L; Platelets 277 ×10⁹/L; Creatinine 58.3 µmol/L; Blood Urea Nitrogen 4.64 mmol/L; Calcium 2.38 mmol/L; Albumin 42 g/L; Total Protein 6.4 g/dL; Glucose 5.01 mmol/L.
- Day 589 (ECOG 1): M Protein 0.2 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 2.35 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 0.54 mg/dL; Immunoglobulin G 9.33 g/L; Immunoglobulin A 0.29 g/L; Immunoglobulin M 0.39 g/L; Lactate Dehydrogenase 2.57 µkat/L; Hemoglobin 8.06 mmol/L; Leukocytes 4.1 ×10⁹/L; Absolute Neutrophil 2.7 ×10⁹/L; Platelets 222 ×10⁹/L; Creatinine 63.6 µmol/L; Blood Urea Nitrogen 4.28 mmol/L; Calcium 2.43 mmol/L; Albumin 46 g/L; Total Protein 7 g/dL; Glucose 5.34 mmol/L.
- Day 651 (ECOG 1): M Protein 0.2 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 1.67 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 0.04 mg/dL; Immunoglobulin G 9.32 g/L; Immunoglobulin A 0.24 g/L; Immunoglobulin M 0.29 g/L; Lactate Dehydrogenase 2.33 µkat/L; Hemoglobin 7.87 mmol/L; Leukocytes 4 ×10⁹/L; Absolute Neutrophil 2.5 ×10⁹/L; Platelets 229 ×10⁹/L; Creatinine 56.6 µmol/L; Blood Urea Nitrogen 5.36 mmol/L; Calcium 2.45 mmol/L; Albumin 47 g/L; Total Protein 6.7 g/dL; Glucose 4.07 mmol/L.
- Day 723 (ECOG 1): M Protein 0.2 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 2.82 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 0.16 mg/dL; Immunoglobulin G 8.68 g/L; Immunoglobulin A 0.29 g/L; Immunoglobulin M 0.26 g/L; Lactate Dehydrogenase 2.53 µkat/L; Hemoglobin 8.31 mmol/L; Leukocytes 4.7 ×10⁹/L; Absolute Neutrophil 3.4 ×10⁹/L; Platelets 202 ×10⁹/L; Creatinine 57.5 µmol/L; Blood Urea Nitrogen 4.28 mmol/L; Calcium 2.4 mmol/L; Albumin 47 g/L; Total Protein 6.9 g/dL; Glucose 4.84 mmol/L.

Other clinical attributes
- Day -13: Weight: 69 kg; Height: 167 cm.

Family history
- Relative with cancer history: yes; Relationship type: Father; Relationship primary diagnosis: Multiple Myeloma; Relationship sex at birth: male.

Biospecimens (2 samples)
- Sample MMRF_2363_1_PB_Whole: Sample type: Blood Derived Normal; Tissue type: Normal; Specimen type: Peripheral Blood NOS; Days to sample procurement: -13 days.
- Sample MMRF_2363_2_BM_CD138pos: Sample type: Primary Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Bone Marrow NOS; Days to sample procurement: -13 days.
